Somatic mutation profile of tumor specimen TCGA-X7-A8M5-01A (aliquot TCGA-X7-A8M5-01A-11D-A423-09) from TCGA case TCGA-X7-A8M5, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 65.8 years (24,036 days).
Specimen TCGA-X7-A8M5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddb7704e-6cce-4234-84bc-31a7e663350a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8M5-10A (Blood Derived Normal), aliquot TCGA-X7-A8M5-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6fc6263-efa9-44e2-9326-a0fe0de5ccec

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 20, Silent 7, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 89/395 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- CSMD2 | c.3773G>A p.R1258Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs906640660, COSV53932581; called by muse, mutect2, varscan2
- DHX16 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs775677381, COSV64564266; called by muse, mutect2, varscan2
- H3-3B | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV54665762; called by muse, mutect2, varscan2
- PSEN1 | c.339A>C p.L113= | Splice Region (SNP) | VAF 30/117 reads (26%) | catalogued as rs1382127121; called by muse, mutect2, varscan2
- SLC24A1 | c.2071_2073del p.K691del | In Frame Del (DEL) | VAF 5/31 reads (16%) | catalogued as rs748047300; called by mutect2, pindel
- TNPO3 | c.2539C>G p.P847A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs774723247; called by muse, mutect2, varscan2
- TTN | c.11396C>T p.S3799F (on ENST00000591111; = p.S3753F on NM_003319.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as CM022259; called by muse, mutect2
- ABCC2 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ATP6V1E1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CDHR1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRYM | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF12L2 | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FGG | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOT1L1 | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- H6PD | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- NEXMIF | c.3919G>A p.D1307N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PRDM1 | c.833A>G p.K278R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCYL2 | c.2276C>T p.S759F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- SNTG1 | c.122A>T p.Q41L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TTN | c.84863A>C p.K28288T (on ENST00000591111; = p.K20864T on NM_003319.4) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.11398A>G p.I3800V (on ENST00000591111; = p.I3754V on NM_003319.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2
- AGO2 | c.444A>G p.S148= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- IFNK | c.609A>G p.L203= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs1346378081; called by muse, mutect2
- KIF9 | c.1401T>C p.D467= | Silent (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- NEXMIF | c.2847G>T p.L949= | Silent (SNP) | VAF 34/105 reads (32%) | called by muse, mutect2, varscan2
- OR7D4 | c.93C>T p.F31= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs142183744; called by muse, mutect2, varscan2
- RIPK3 | c.612C>T p.V204= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs753880129; called by muse, mutect2, varscan2
- SH3TC1 | c.1896G>A p.L632= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs745306608; called by muse, mutect2, varscan2
